Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A2N9, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A2N9-01A (Primary Tumor).

ADDENDA:
Addendum

Collection Date:

MOLECULAR ANATOMIC PATHOLOGY TESTING:

Part 1:

Mutations in *BRAF*, *NRAS61*, *HRAS61*, *KRAS12/13*, and *RET/PTC1*, *RET/PTC3* and *PAX8/PPARg* rearrangements NOT identified.

NOTE:

Nucleic acids were extracted in the amount sufficient for testing. Amplification of *GAPDH* and *KRT7* controls was acceptable.

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY (27 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, ENCAPSULATED ONCOCYTIC FOLLICULAR VARIANT (2.5 CM), RIGHT LOBE, CONFINED TO THE THYROID; NO CAPSULAR OR ANGIOLYMPHATIC INVASION PRESENT.
- B. THREE (3) LYMPH NODES, NO TUMOR PRESENT (0/3).
- C. PATHOLOGIC STAGE: pT2 N0.
- D. EXUBERANT CHRONIC LYMPHOCYTIC THYROIDITIS.

PART 2: LYMPH NODES, CENTRAL COMPARTMENT, SELECTIVE DISSECTION -
EIGHT (8) LYMPH NODES, NO TUMOR PRESENT (0/8).

COMMENT:

This case has been reviewed by my colleague,
studies will be performed and reported as an addendum.

who agrees with the above diagnosis. Molecular

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:

Total Thyroidectomy

TUMOR FOCALITY:

Unifocal

TUMOR SIZE (largest nodule):

Greatest Dimension: 2.5 cm

HISTOLOGIC TYPE**:

Papillary carcinoma, encapsulated follicular variant

PRIMARY TUMOR (pT):

pT2

REGIONAL LYMPH NODES (pN):

pN0

Number of regional lymph nodes examined: 11

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM):

Not applicable

EXTRATHYROIDAL EXTENSION:

Not identified

MARGINS:

Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION:

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Thyroiditis

1CD-0-3

carcinoma, papillary, follicular variant 8340/3
Site: thyroid, NOS c73.9

on 8/18/11

Source: NCI Genomic Data Commons file c287cf26-6f2c-40a5-90e1-9589d990716a (TCGA-BJ-A2N9.53203C6A-0B8E-4563-A150-21E3F8F3A0E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).